Surgical pathology report (de-identified scan), TCGA case TCGA-JW-A5VL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site BLN - Baylor, specimen TCGA-JW-A5VL-01A (Primary Tumor).

[page 1 of 3]
Result History

Result Date and Time

Status

Priority

Final result

Routine

Report Assistance Message

Component Results

Surgical Pathology:

(note)

Name

Date on

Hospital

Location

SURGICAL PATHOLOGY

Accession #:

Collected:

Received:

ICD-0-3

Carcinoma, papillary squamous cell,
non-invasive 8052/2

Site: cervix NOS C53.9

hw
4/18/13

PATHOLOGIC DIAGNOSIS

UTERINE CERVIX, BIOPSY:

- PAPILLARY FRAGMENTS OF SQUAMOUS CELL CARCINOMA
- SEE COMMENT

Staff Pathologist

COMMENT: Sections of the biopsy show fragments of squamous cell carcinoma with papillary architecture and fibrovascular cores. A fragment with scant desmoplastic stroma is identified, but no definitive invasion is identified.

Staff Pathologist

Pertinent Clinical Information

Cervical cancer, 6 cm cervical mass.

Procedure: EUA, proctoscopy, cystoscopy, cervical biopsy.

Gross Description

4/19/13 - after further review of BCR lead
pathologist, case determined to be
non-invasive. DQ. hw

Diagnosis Discrepancy	hw 2/17/13	☒
HIIPAA Discrepancy		☒

[page 2 of 3]
Specimen Material: Cervical biopsy.

The case is received in one part labeled with the patient's name, medical record number and given accession number, and it is accompanied by a requisition form labeled with the same name and accession number.

Received in formalin labeled "CERVICAL BIOPSY" are two tan-gray tissues ranging from 0.2 x 0.2 x 0.1 cm to 0.7 x 0.4 x 0.2 cm which are submitted in toto following filtration in a cassette.

Pathology Assistant

Microscopic Description
Performed.

Intradepartmental consultation: was examined this case and agrees with the findings and interpretation.

This case was reviewed by the staff pathologist listed below.

Pathology Resident
Electronically Signed Out

Staff Pathologist

Result History

Result Date and Time

Status

In process

Priority

Routine

Report Assistance Message

Results Routing Details for Order:

Outcome:	Routed using the authorizing provider	
Routing Scheme Used:		
Routing Scheme Line:	2	
Resulting User:		
Routing Instant:		
Comments:	Routing scheme returned no recipients	
Current Status:	Routing Complete	
Status History:	Result contact created	
	Routing started	
	Routing Complete	
Sent:	Message ID:	Recipients:
	responsible: Yes	
	Provider ID: Provider defined by Results Routing)	
	Result routed to linked user	
Outcome:	Result not sent	
Resulting User:		

[page 3 of 3]
Routing Instant:	
Comments:	An message was not sent because no results were filed
Current Status:	Routing Complete
Status History:	Result contact created Routing Complete

Order Transmittal Details for Order:
There is no tracking information for this order. Either the order has not gone through order transmittal or the tracking data has been purged from the system due to age.

Performance Data For

Source: NCI Genomic Data Commons file befbdbe4-93be-4a92-ba97-839030314661 (TCGA-JW-A5VL.7C385D8F-CFDF-48DC-B421-4B2483CE9B25.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).